Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-6223, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-6223-01A (Primary Tumor).

[page 1 of 4]
Specimen(s) Received

1. Nck: Right neck level II
2. Nck: Right neck level III
3. Nck: Right neck level IV
4. Neck:medial anterior mucosa margin
5. Neck:medial posterior mucosa margin
6. NeckPosterior buccal superficial margin
7. Neck:posterior buccal deep margin
8. NECK:PTERYGOID DEEP MARGIN
9. Neck; right posterior mandible margin
10. Neck: medial mandible margin

Diagnosis

1. Right neck; level II:
- Ten lymph nodes, negative for malignancy (0/10).
- Submandibular gland with no pathologic changes.
2. Right neck; level III:
- Two lymph nodes, negative for malignancy (0/2).
3. Right neck; level IV:
- Twenty lymph nodes, negative for malignancy (0/20).
4. Medial anterior mucosa margin:
- Negative for malignancy.
5. Medial posterior mucosa margin:
- Negative for malignancy.
6. Posterior buccal superficial margin:
- Negative for malignancy.

[page 2 of 4]
7. Posterior buccal deep margin:
- Negative for malignancy.
8. Pterygoid deep margin:
- Negative for malignancy.
9. Right posterior mandible; composite resection:
- Squamous cell carcinoma, moderately differentiated.
- a. The tumour is present in the alveolar ridge.
- b. Maximum tumour size is 2.5 cm.
- c. Maximum tumour thickness is 0.5 cm.
- d. No perineural invasion identified.
- e. No lymphovascular invasion identified.
- f. Margins of resection are free of tumour.
- g. Bone sections are pending decalcification and will be reported as an addendum.
10. Medial mandible margin:
- Bone sections are pending decalcification and will be reported in an addendum.

Synoptic Data

Specimen Type:	Resection: Composite mandible resection.
Tumor Site:	Oral Cavity
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 2.5 cm
	Tumor thickness: 0.5 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Absent
Margins:	Margins uninvolved by tumor
Pathologic Staging (pTNM):	pTX: Primary tumor of lip or oral cavity cannot be assessed
	pN0: No regional lymph node metastasis for aerodigestive sites
	Number of regional lymph nodes examined: 32
	Number of regional lymph nodes involved: 0
	pMX: Distant metastasis cannot be assessed

Comment

The T-stage of the tumour is deferred in the synoptic report pending bone sections.

Electronically

verified by:

Clinical History

Oral CA

Gross Description

1. The specimen labeled with the patient's name and as "right neck level II" consists of a piece of fibroadipose tissue that measures 6.0 x 3.5 x 2.0 cm and contains multiple lymph nodes that

[page 3 of 4]
range from 0.2 to 1.1 cm. Also present is a submandibular gland measuring 0.5 cm x 2.5 cm x 1.2 cm. Serial cuts of the submandibular gland are grossly unremarkable. Representative sections are submitted.

1A submandibular gland

1B-1D multiple lymph nodes, per block

2. The specimen labeled with the patient's name and as "right neck level III" consists of a piece of fibroadipose tissue that measures 4.5 x 4.0 x 1.5 cm and contains 2 lymph nodes that measure 0.3 and 2.1 cm. Also present in the specimen are a portion of muscle measuring 3.0 x 2.0 x 0.5 cm and a vessel measuring 2.5 cm in length by 0.4 cm in diameter. Both of these are grossly unremarkable. Representative sections are submitted.

2A muscle

2B 2 lymph nodes

3. The specimen labeled with the patient's name and as "right neck level IV" consists of a piece of fibroadipose tissue that measures 4.2 x 4.0 x 1.5 cm and contains multiple lymph nodes that range from 0.2 to 1.4 cm. Small fragments of muscle are grossly unremarkable on serial sectioning. Representative sections are submitted.

3A-3E multiple lymph nodes, per block

3F muscle

Four. The specimen is labeled with the patient's name and as "medial anterior mucosa margin". It consists of a fragment of tissue measuring 0.6 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.

4A frozen section control

5. The specimen is labeled with the patient's name and as "medial posterior mucosa margin". It consists of a fragment of tissue measuring 1.2 x 0.2 x 0.1 cm. The specimen is submitted in toto for frozen section.

5A frozen section control

6. The specimen is labeled with the patient's name and as "posterior buccal superficial margin". It consists of a fragment of tissue measuring 1.2 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.

6A frozen section control

7. The specimen is labeled with the patient's name and as "posterior buccal deep margin". It consists of 2 fragments of tissue measuring 0.6 x 0.6 x 0.2 cm and 1.0 x 0.2 x 0.2 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

8. The specimen is labeled with the patient's name and as "pterygoid deep margin". It consists of a fragment of tissue measuring 0.9 x 0.2 x 0.2 cm. The specimen is submitted in toto for frozen section.

8A frozen section control

9. The specimen is labeled with the patient's name and as "RT posterior mandible". It consists of a composite resection measuring 6.3 AP x 2.7 SI x 2.5 ML cm. It includes a portion of right posterior mandible with no teeth. There is a tumor arising in the mucosa of the alveolar ridge. The tumor measures 2.5 AP x 0.5 SI x 1.4 ML cm. The tumor is well circumscribed. It has a nodular center with a rolled edge. The cut surface is white-tan and firm. There is possible involvement of bone by the tumour. The tumor is located at 0.5 cm from the closest medial

[page 4 of 4]
mucosal margin. Remaining margins are as follows: Anterior mucosa 1.3 cm, posterior mucosa .2 cm, lateral mucosa - 1.2 cm, deep medial margin - 1.2 cm, deep lateral margin - 0.6 cm, anterior bony margin - 1.3 cm, posterior bony margin - 1.9 cm. Representative sections are submitted.

9A anterior margin, en face

9B tumor with posterior margin

9C tumor with medial and medial deep soft tissue margin

9D tumor with lateral and lateral deep soft tissue margin

9E tumor

9F tumor with underlying bone, after decalcification

9G anterior bony resection margin, en face, after decalcification

9H posterior bony resection margin, en face, after decalcification

10. The specimen is labeled with the patient's name and as "medial mandible margin". It consists of an unoriented piece of bone measuring 2.5 x 1.0 cm with a maximum thickness of 0.6 cm. The bone is yellow-tan and shows small fragments of adherent muscle and tendon. The cut surface shows a central portion of trabecular bone with outer cortical bone. The specimen is decalcified.

10A submitted in toto, after decalcification

Quick Section Diagnosis

4A – Negative for malignancy

5A – Negative for malignancy

6A – Negative for malignancy

7A – Negative for malignancy

8A – Negative for malignancy

Slides received from [REDACTED] [REDACTED] Reported to [REDACTED] at [REDACTED]

Addendum

Out

Status: Signed

Date Reported:

Addendum Diagnosis

9. Right posterior mandible (bone sections):

- Squamous cell carcinoma is present adjacent to the bone, with no evidence of bone invasion.
- The bone margins are negative for malignancy.

10. Medial mandible margin (bone section):

- Bone with no pathologic changes, negative for malignancy.
-

Source: NCI Genomic Data Commons file d17cb7c9-3684-424d-abda-2d78b7e9eb0a (TCGA-CQ-6223.2D5F1182-192C-4D2E-94F0-2E543C3CF1C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).